Somatic mutation profile of tumor specimen TCGA-DU-7006-01A (aliquot TCGA-DU-7006-01A-11D-2024-08) from TCGA case TCGA-DU-7006, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 60.2 years (21,990 days).
Specimen TCGA-DU-7006-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee0f8df6-6add-4cbd-86b6-74e7e7c9aef6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7006-10A (Blood Derived Normal), aliquot TCGA-DU-7006-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00a05d61-752b-4680-a602-d9520f3e57cf

The open-access MAF lists 53 somatic variants for this specimen: 43 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Nonsense Mutation 6, Silent 6, RNA 2, Intron 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.755G>C p.R252P | Missense Mutation (SNP) | VAF 17/140 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as COSV51785413, COSV51800797; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.6266C>T p.P2089L | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60922479; called by muse, mutect2, varscan2
- AK7 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs767780619, COSV50871179; called by muse, mutect2, varscan2
- ATP13A3 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs776496097, COSV55467258; called by muse, mutect2, varscan2
- C20orf194 | c.3178C>T p.Q1060* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as COSV52699267; called by muse, mutect2, varscan2
- CACNA1E | c.3691G>A p.V1231I | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.806); catalogued as rs376915340, COSV62403340; called by muse, mutect2, varscan2
- CLTC | c.2278A>C p.K760Q | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52249944; called by muse, mutect2
- EIF4G1 | c.2926C>T p.R976C (on ENST00000346169 / NM_198241.3; = p.R781C on NM_004953.5) | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV59992382; called by muse, mutect2, varscan2
- FAM135B | c.3971C>A p.A1324D | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52739973, COSV99425923; called by muse, mutect2, varscan2
- FBN1 | c.297G>A p.M99I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as rs1314594090, COSV57324089; called by muse, mutect2, varscan2
- FBP2 | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs557921747, COSV64694500; called by muse, mutect2, varscan2
- GATA6 | c.442T>A p.Y148N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV52526803, COSV99333532; called by muse, mutect2, varscan2
- GPRC6A | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199585628, COSV59954650; called by muse, mutect2, varscan2
- KCNT2 | c.3331C>T p.P1111S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV54093828; called by muse, mutect2, varscan2
- MAEA | c.530C>G p.T177S | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.105); catalogued as COSV53263679; called by muse, mutect2, varscan2
- MAST2 | c.3627G>C p.K1209N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as COSV63619975; called by muse, mutect2, varscan2
- MEGF10 | c.3025G>A p.D1009N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.196); catalogued as COSV57253216; called by muse, mutect2, varscan2
- NDC1 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52337003; called by muse, mutect2, varscan2
- NEK10 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as COSV58286515; called by muse, mutect2, varscan2
- NEK9 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as COSV53132268; called by muse, varscan2
- NPR3 | c.674A>T p.Q225L | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV54090389; called by muse, mutect2
- OGT | c.2527G>T p.V843L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as COSV65481873, COSV65482220; called by muse, mutect2, varscan2
- OR4N2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770622276, COSV60050519; called by muse, varscan2
- PAK1IP1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV65435240, COSV65435681; called by muse, mutect2, varscan2
- PCDHGA5 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.043); catalogued as COSV53896726; called by muse, mutect2, varscan2
- PIK3R3 | c.4_7dup p.N3Ifs*11 | Frame Shift Ins (INS) | VAF 15/52 reads (29%) | catalogued as rs779875823; called by mutect2, pindel, varscan2
- PJVK | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57869691; called by muse, mutect2
- PPARG | c.262C>G p.P88A (on ENST00000287820 / NM_015869.5; = p.P58A on NM_005037.7) | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.089); catalogued as COSV55143972; called by muse, mutect2, varscan2
- PSG2 | c.185T>A p.L62H | Missense Mutation (SNP) | VAF 96/328 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV68885031; called by muse, mutect2, varscan2
- RBM46 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as rs866164836, COSV55977357; called by muse, mutect2, varscan2
- ROBO4 | c.2374G>A p.V792M | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs371875012; called by muse, mutect2, varscan2
- RPL10L | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs758921040, COSV53558822, COSV53559285; called by muse, mutect2, varscan2
- SACS | c.10271G>A p.G3424E | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV66544033, COSV66546108; called by muse, mutect2, varscan2
- SBF1 | c.2497T>A p.F833I | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62369143; called by muse, mutect2, varscan2
- SRRM1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.992); catalogued as rs763456982, COSV60479173; called by muse, mutect2, varscan2
- ST8SIA2 | c.127T>G p.S43A | Missense Mutation (SNP) | VAF 22/57 reads (39%) | PolyPhen benign (0.169); catalogued as COSV51571227; called by muse, mutect2, varscan2
- TBC1D25 | c.1658C>G p.S553C | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV65124122; called by muse, mutect2, varscan2
- THOC2 | c.4598C>G p.S1533* | Nonsense Mutation (SNP) | VAF 37/105 reads (35%) | catalogued as COSV55550966, COSV99834161; called by muse, mutect2, varscan2
- TMPRSS6 | c.2248C>T p.Q750* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV60981178; called by muse, mutect2, varscan2
- TRPC3 | c.600C>A p.F200L (on ENST00000379645 / NM_001366479.2; = p.F127L on NM_003305.2) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53375722, COSV53378284; called by muse, mutect2, varscan2
- TSNARE1 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as rs1276150478, COSV56179823; called by muse, mutect2, varscan2
- ZNF106 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1397850024, COSV55519158; called by muse, mutect2, varscan2
- ALPK3 | c.687G>A p.G229= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV51929087, COSV51936517; called by muse, mutect2, varscan2
- FAM199X | c.138C>T p.F46= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1556374100, COSV72419797; called by muse, mutect2
- FBN3 | c.6462C>T p.D2154= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as rs776542955, COSV54456098; called by muse, mutect2, varscan2
- GPC3 | c.327G>A p.A109= | Silent (SNP) | VAF 71/242 reads (29%) | catalogued as rs1466168469, COSV63668186; ClinVar: likely benign; called by muse, mutect2, varscan2
- MCM3AP | c.1509C>T p.H503= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV52442723; called by muse, mutect2
- SCP2D1 | c.168G>A p.R56= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs143971555, COSV53858051; called by muse, mutect2, varscan2
- EPHA8 | c.1315+18G>A | Intron (SNP) | VAF 16/44 reads (36%) | catalogued as rs199679973, COSV51273871; called by muse, mutect2, varscan2
- MIR372 | n.51C>T | RNA (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- PKD1L2 | n.852C>T | RNA (SNP) | VAF 33/124 reads (27%) | catalogued as rs773392210; called by muse, mutect2, varscan2
- PRR12 | chr19:49595072 A>G | 5'Flank (SNP) | VAF 6/22 reads (27%) | catalogued as COSV55870849; called by muse, mutect2, varscan2
